Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WX-01A (Primary Tumor).

Gross:

Right adrenal with ovoid fibrously encapsulated tumor (60x50x38 mm, 55 g). On cut, grey-pink tumor with soft consistency. Adrenal cortex remnants with pressure atrophy are seen subcapsularly on periphery.

Micro:

Solid, diffusively growing pheochromocytoma consisting from large polygonal cells with focal hemorrhages. On periphery, adrenal cortex remnants were confirmed histopathologically. Focally, they are completely eroded. In examined excisions, no invasion behind the capsule was found.

Imunohistochemic examination:

Staining with S100 protein confirmed sustentacular cells in a tumor part, some tumor parts showed negative staining for S100 protein. Proliferation activity (MIB-1) was minimal – less than 1%

PASS

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 4

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma, malignant
8700/3
Site: Adrenal gland NOS
C74.9
9/10/13

Source: NCI Genomic Data Commons file 719e9841-b41c-4a35-9c29-0ddff53392ea (TCGA-S7-A7WX.587908C3-1863-4C5A-8FE4-171BAED7B213.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).